Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADO, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADO-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: R/O HCC, Seg 7-8

Specimen : liver

Gross Photo :

GROSS:

Specimen:

Liver: 18.0 x 13.5 x 10.0 cm, 930.5 gm, unfixed

Gallbladder: 10.3 cm in length, 3.8 cm in diameter, unfixed

Operation: Hemihepatectomy, right

Lesion:

A well demarcated irregular shape mass (12.0 x 11.5 x 10.0 cm)

Cut surface: Yellowish tan, and granular with necrosis (30 %)

Gross type

HCC: Multinodular confluent

Resection margin: Very close (less than 0.1 cm)

Others: Satellite nodule: No

Remaining parenchyma: Unremarkable

Portal vein invasion: No

Gross photo: Present

Blocks

T1-6 and TB, tumor and surrounding tissue x 7

RM, resection margin x 1

L and NB, remaining liver parenchyme x 2

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

Edmondson-Steiner grade

The worst grade III

The major grade III

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Cholangiocarcinoma: No

Combined hepatocellular and cholangiocarcinoma: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion: No, margin of the clearance (less than 0.1 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: Yes

Intrahepatic metastasis: No

ICD.O-3

Carcinoma, hepatocellular NOS
8170L3

Sate. Liver NOS
C22.0

9/20/14

[page 2 of 2]
Multicentric occurrence: No

NOT reported. Gross:

NOT reported. Gross:

Pleural fluid, smear, inflammation

Pleural fluid, smear, inflammation

Liver, ectomy, Hepatocellular carcinoma

T56000, P10, M81703

Gallbladder, ectomy, Chronic cholecystitis

T57000, P10, M43005

DIAGNOSIS:

Liver, right hemihepatectomy: Hepatocellular carcinoma

Gallbladder, cholecystectomy: Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file 3774386a-3199-48f1-baf7-2755ca47436f (TCGA-DD-AADO.7A832B85-3B55-44E5-AC66-35DBADADEAEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).